Somatic mutation profile of tumor specimen C3N-01178-02 (aliquot CPT0078990009) from CPTAC case C3N-01178, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.8 years (21,476 days).
Specimen C3N-01178-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14ee220b-af08-4afa-b270-80ccd76f43b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01178-31 (Blood Derived Normal), aliquot CPT0079040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bdd7b75-c503-4524-a604-57b003192977

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Splice Region 4, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.393C>T p.D131= | Splice Region (SNP) | VAF 43/168 reads (26%) | catalogued as rs774589225, COSV53113802; called by muse, mutect2, varscan2
- CFAP47 | c.9069G>T p.W3023C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66217834; called by muse, mutect2, varscan2
- GFRA3 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as rs1261855998; called by muse, mutect2, varscan2
- GPR132 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs376184785; called by muse, mutect2, varscan2
- MLPH | c.108A>G p.L36= | Splice Region (SNP) | VAF 92/490 reads (19%) | catalogued as rs1173832235; called by muse, mutect2, varscan2
- MMP7 | c.152dup p.N51Kfs*51 | Frame Shift Ins (INS) | VAF 25/122 reads (20%) | catalogued as rs749814192; called by mutect2, pindel, varscan2
- MUC16 | c.33529C>T p.P11177S | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.428); catalogued as rs950027319; called by muse, mutect2, varscan2
- NFIA | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 57/127 reads (45%) | catalogued as rs1553149167, CM124520, COSV64537221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD54L | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 144/619 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.214); catalogued as rs770214317; called by muse, mutect2, varscan2
- RPL22 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52377548; called by muse, mutect2, varscan2
- VHL | c.528del p.R177Dfs*25 | Frame Shift Del (DEL) | VAF 192/579 reads (33%) | catalogued as COSV56568222; called by mutect2, pindel, varscan2
- ZBTB7C | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV59687630; called by muse, mutect2, varscan2
- ZNF408 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1231985813, COSV61239620; called by muse, mutect2, varscan2
- ABCA3 | c.1601A>G p.H534R | Missense Mutation (SNP) | VAF 149/507 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ABCC8 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- AFF1 | c.1038+3G>T | Splice Region (SNP) | VAF 56/289 reads (19%) | called by muse, mutect2, varscan2
- ALG13 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ANO7 | c.1640T>A p.L547H (on ENST00000274979; = p.L493H on NM_001370694.2) | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- APAF1 | c.3707A>G p.D1236G (on ENST00000551964 / NM_181861.2; = p.D1182G on NM_001160.3) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- CACNB3 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNG6 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L1 | c.448-4_451del p.X150_splice | Splice Site (DEL) | VAF 79/388 reads (20%) | called by mutect2, pindel, varscan2
- GARNL3 | c.2150T>G p.L717W | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0895 | c.1344del p.L449Ffs*10 (on ENST00000297063 / NM_001100425.2; = p.L398Ffs*10 on NM_015314.3) | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- KLHL40 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP1A | c.2446G>T p.V816L | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MAPK6 | c.1220A>G p.E407G | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAST4 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MED16 | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MUC20 | c.2095T>C p.F699L | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2F2 | c.707_710dup p.Q237Hfs*73 | Frame Shift Ins (INS) | VAF 109/461 reads (24%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1179C>A p.N393K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OSBPL2 | c.233C>A p.T78N (on ENST00000313733 / NM_144498.4; = p.T66N on NM_014835.4) | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH7 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PNP | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 106/435 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- PRR14L | c.1451A>C p.Q484P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RANBP2 | c.7380A>C p.R2460S | Missense Mutation (SNP) | VAF 71/428 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RUFY2 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINI2 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC22A17 | n.706C>A | Splice Region (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1858A>T p.S620C | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- THPO | c.1063G>A p.G355S (on ENST00000649095 / NM_001290003.1; = p.G215S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRAPPC13 | c.1115_1117del p.L372_T373delinsP | In Frame Del (DEL) | VAF 34/104 reads (33%) | called by mutect2, pindel, varscan2
- WHAMM | c.1925C>A p.P642H | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XDH | c.1415G>C p.R472T | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF670 | c.946_952del p.K316Sfs*17 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ABCC9 | c.3552C>A p.T1184= | Silent (SNP) | VAF 47/253 reads (19%) | catalogued as COSV53972433; called by muse, mutect2, varscan2
- BAHCC1 | c.6402G>A p.Q2134= | Silent (SNP) | VAF 72/297 reads (24%) | called by muse, mutect2, varscan2
- CCDC74B | c.1123C>T p.L375= | Silent (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- CNTRL | c.4923C>T p.H1641= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, varscan2
- CUL9 | c.1266G>A p.S422= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as rs767726918, COSV52734096; called by muse, mutect2, varscan2
- DCAF8 | c.1572G>A p.K524= | Silent (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- DNAH10 | c.13497C>T p.N4499= (on ENST00000409039; = p.N4438= on NM_207437.3) | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs750482067, COSV99435965; called by muse, mutect2, varscan2
- GNA14 | c.471G>A p.L157= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- KLHDC10 | c.576G>A p.K192= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs1243378955; called by muse, mutect2, varscan2
- PHLDA1 | c.81G>T p.P27= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs564932662; called by muse, mutect2, varscan2
- SMURF1 | c.1224C>A p.I408= | Silent (SNP) | VAF 71/267 reads (27%) | catalogued as COSV100742475; called by muse, mutect2, varscan2
- TTLL13P | c.618C>T p.G206= | Silent (SNP) | VAF 44/268 reads (16%) | called by muse, mutect2, varscan2
- ATP2C1 | c.-17C>T | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- GLT8D2 | c.112+2194A>G | Intron (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- MAP2K1 | c.568+8781A>T | Intron (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- ZACN | c.545-400A>G | Intron (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
